Somatic mutation profile of tumor specimen TCGA-QR-A70O-01A (aliquot TCGA-QR-A70O-01A-11D-A35D-08) from TCGA case TCGA-QR-A70O, project TCGA-PCPG (Pheochromocytoma and Paraganglioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Pheochromocytoma, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 35.8 years (13,076 days).
Specimen TCGA-QR-A70O-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3e702c39-85bc-4f4d-afbd-eae5cfdb196f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-QR-A70O-10A (Blood Derived Normal), aliquot TCGA-QR-A70O-10A-01D-A35B-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e6113457-05e0-40ff-9aa9-a72e9c2742c2

The open-access MAF lists 12 somatic variants for this specimen: 11 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 9, Silent 1, Splice Site 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PPP1R17 | c.236-2A>T p.X79_splice | Splice Site (SNP) | VAF 24/61 reads (39%) | catalogued as rs933423297; called by muse, mutect2, varscan2
- SUSD6 | c.170C>T p.P57L | Missense Mutation (SNP) | VAF 19/89 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61365688; called by muse, mutect2, varscan2
- TIMELESS | c.1190G>T p.G397V | Missense Mutation (SNP) | VAF 29/55 reads (53%) | SIFT tolerated (0.08); PolyPhen benign (0.074); catalogued as rs762811260; called by muse, mutect2, varscan2
- CEACAM5 | c.277C>T p.P93S | Missense Mutation (SNP) | VAF 125/243 reads (51%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- CMYA5 | c.6584A>G p.K2195R | Missense Mutation (SNP) | VAF 5/87 reads (6%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.014); called by muse, mutect2
- CREB3 | c.657_658del p.E219Dfs*31 | Frame Shift Del (DEL) | VAF 51/147 reads (35%) | called by pindel, varscan2
- OR2A2 | c.525C>A p.H175Q | Missense Mutation (SNP) | VAF 30/141 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.491); called by muse, mutect2, varscan2
- PRR12 | c.1625G>A p.C542Y (on ENST00000615927; = p.C1363Y on NM_020719.3) | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.551); called by muse, mutect2
- SULT6B1 | c.459C>A p.H153Q (on ENST00000535679 / NM_001367551.1; = p.H115Q on NM_001032377.2) | Missense Mutation (SNP) | VAF 46/114 reads (40%) | SIFT tolerated (0.21); PolyPhen benign (0.09); called by muse, mutect2, varscan2
- ZNF419 | c.988C>G p.L330V | Missense Mutation (SNP) | VAF 32/62 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.667); called by muse, mutect2, varscan2
- ZNF773 | c.952C>G p.L318V | Missense Mutation (SNP) | VAF 17/177 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- LEFTY1 | c.183C>T p.Y61= | Silent (SNP) | VAF 9/25 reads (36%) | catalogued as rs570726921; called by muse, mutect2, varscan2
